TCGA case TCGA-J9-A8CM — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: Melbourne Health. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/deceb7df-6edc-41f0-99aa-c4ac7e764074

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 66.0 years (24,118 days); Year of diagnosis: 2013; Method of diagnosis: Core Biopsy; AJCC clinical T: T2c; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N1; Primary gleason grade: Pattern 5; Secondary gleason grade: Pattern 4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Gleason score: 9.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 14; Tumor level prostate: Apex / Middle / Base; Zone of origin prostate: Peripheral zone.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 14 (initial diagnosis): Days to imaging: 14 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Day 344 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 344 days.
- Days to follow up: 463 days (1.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.55 ng/mL (day 463).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-J9-A8CM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 230 mg.
  Slide TCGA-J9-A8CM-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-J9-A8CM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: No; Diagnostic mri performed: No; Lymph nodes examined: Yes; Treatment outcome first course: Partial Remission/Response; Biochemical recurrence indicator: Yes; New tumor event diagnosis indicator: Yes.
- Tumor levels: Tumor level: Apex; Tumor level: Middle; Tumor level: Base.
- Stage record, Psa: PSA most recent results: 0.55.
- Stage record, Gleason grading: Gleason pattern primary: 5; Gleason pattern secondary: 4; Gleason pattern tertiary: 3.
- New tumor event: New tumor event type: Biochemical evidence of disease; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 463 days; disease-specific survival: no event (censored), 463 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 344 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-J9-A8CM-01A-11D-A34T-01): tumor purity 0.62, ploidy 2.03, whole-genome doublings 0.
